Surgical pathology report (de-identified scan), TCGA case TCGA-G7-6796, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-6796-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. LEFT RENAL MASS
- B. ADDITIONAL TUMOR
- C. LEFT RENAL FINAL MARGIN
- D. FINAL RANDOM MARGIN
- E. FAT OVERLYING KIDNEY-LEFT

SPECIMEN(S):

- A. LEFT RENAL MASS
- B. ADDITIONAL TUMOR
- C. LEFT RENAL FINAL MARGIN
- D. FINAL RANDOM MARGIN
- E. FAT OVERLYING KIDNEY-LEFT

CLINICAL HISTORY

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSC/FSD- Negative for tumor by Dr. to Dr. at [REDACTED]

GROSS DESCRIPTION:

A. LEFT RENAL MASS

Received fresh is a piece of yellow-tan soft tissue weighing 13 g and measuring 3.7 x 2.8 x 2 cm. There is a suture designating the site of additional tumor resection. The indicated surface is inked blue and the opposite surface is inked black. The specimen is bisected; there is a well-circumscribed gold-tan mass measuring 1.5 x 1.3 x 1.2 cm which is located adjacent to the tumor resection margin. The mass is hemorrhagic and necrotic. Portion is submitted for procurement. The adjacent fat is unremarkable. The specimen is submitted entirely in cassettes A1-A8.

B. ADDITIONAL TUMOR-LEFT RENAL

Received in formalin is a piece of brown-tan tissue measuring 1.7 x 1.5 x 1.2 cm. There is a area white-tan discoloration measuring 0.9 x 0.9 x 0.2 cm. The renal tissue is inked black. The specimen is serially sectioned and submitted entirely in cassettes B1-B2.

C. LEFT RENAL FINAL MARGIN

Received fresh are 3 small tan-red tissue fragments measuring 0.6 x 0.4 cm in aggregate. Submitted entirely for frozen section diagnosis in cassette FSC1.

D. FINAL RANDOM MARGIN

Received fresh are 4 tan tissue fragments measuring 0.8 x 0.5 cm in aggregate. Submitted entirely for frozen section diagnosis in cassette FSD1.

E. FAT OVERLYING KIDNEY-LEFT

Received in formalin is an aggregate of yellow-tan adipose tissue measuring 20 x 14 x 4 cm. On sectioning, no masses, lesions, or areas of discoloration are identified. Representative sections are submitted in cassette E1-E3.

DIAGNOSIS:

A. KIDNEY, LEFT, PARTIAL NEPHRECTOMY:

- RENAL CELL CARCINOMA, PAPILLARY TYPE, FUHRMAN GRADE 2, CONFINED TO KIDNEY, MEASURING 1.5 CM
- RESECTION MARGINS NEGATIVE FOR TUMOR
- SEE SYNOPSIS REPORT.

B. KIDNEY, LEFT, ADDITIONAL TUMOR AND FINAL MARGIN, EXCISION:

- PAPILLARY RENAL CELL CARCINOMA
- MARGINS NEGATIVE FOR TUMOR.

C. KIDNEY, LEFT, FINAL MARGIN, EXCISION:

- FRAGMENTS OF RENAL PARENCHYMA, NO TUMOR SEEN.

D. KIDNEY, LEFT FINAL RANDOM MARGIN, EXCISION:

- FRAGMENTS OF RENAL PARENCHYMA, NO TUMOR SEEN.

[page 2 of 2]
E. SOFT TISSUE, OVERLAYING LEFT KIDNEY, EXCISION:
- FIBROADIPOSE TISSUE, NO TUMOR SEEN.

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimen Type: Partial nephrectomy

Without adrenal gland

Laterality: Left

Tumor Site: Not specified

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 1.5cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Papillary renal cell carcinoma 8260/3

Histologic Grade (Fuhrman Nuclear Grade): G2: Nuclei slightly irregular, approximately 15 u;
nucleoli evident

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Not present

Regional Lymph Nodes: None sampled

Additional Findings: None identified

Pathological Staging (pTNM): pT 1a N X M X

PRE-OPERATIVE DIAGNOSIS:

Left renal mass

Source: NCI Genomic Data Commons file dcdf5cc9-9da3-4b09-8bb3-dbb0b2b3d777 (TCGA-G7-6796.A2225324-A065-40DA-B564-F7130670CC87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).